Somatic mutation profile of tumor specimen TCGA-OR-A5KQ-01A (aliquot TCGA-OR-A5KQ-01A-11D-A30A-10) from TCGA case TCGA-OR-A5KQ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 20.4 years (7,459 days).
Specimen TCGA-OR-A5KQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0411b56-886e-4115-940b-59dc1b15e548.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KQ-10A (Blood Derived Normal), aliquot TCGA-OR-A5KQ-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9385a8d2-cfcd-45dc-9f55-dc6390cdc419

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A2 | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 55/370 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1558008569, COSV63403100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC120 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782816201, COSV64515054; called by mutect2, varscan2
- ECEL1 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs775694744, COSV58812940; called by muse, mutect2, varscan2
- MECP2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1557134934; called by muse, mutect2, varscan2
- SLIT2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333523681, COSV56588499; called by muse, mutect2
- ARHGAP11A | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- OMG | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A3 | c.2126T>G p.F709C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, varscan2
- KLRC2 | c.525G>A p.V175= | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- MTHFD1L | c.2070T>C p.S690= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- USP31 | c.3735C>A p.G1245= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
